Gene-level copy-number profile of tumor specimen TCGA-77-7138-01A from TCGA case TCGA-77-7138, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.3 years (24,594 days).
Specimen TCGA-77-7138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.537d62e6-8c94-4396-8683-bad4c9aff415.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7138-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dcf1c10-c31e-49d5-b9bb-31d27488eabc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,559; copy number 2: 25,509; copy number 3: 21,756; copy number 4: 1,117; copy number 5: 2,256; copy number 6: 211; copy number 7: 499; copy number 8: 819; copy number 9: 7; copy number 10: 6; copy number 14: 79.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,575 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–2,835,139, 85 genes, copy number 10–14 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 7–8 (broad region; genes not listed).
- chr8:97,775,057–97,853,013, 2 genes, copy number 6 (within-gene range 3–6): LAPTM4B, AP003357.1.
- chr8:100,572,889–102,154,725, 43 genes, copy number 5: SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1.
- chr13:68,634,190–114,337,626, 566 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,066. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
